Somatic mutation profile of tumor specimen TCGA-14-2554-01A (aliquot TCGA-14-2554-01A-01D-1494-08) from TCGA case TCGA-14-2554, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.3 years (19,090 days).
Specimen TCGA-14-2554-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa743f49-ee74-4eb2-ad58-d4e525520224.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-2554-10A (Blood Derived Normal), aliquot TCGA-14-2554-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee7bf22-d609-484f-a270-435e7a910cea

The open-access MAF lists 72 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, RNA 3, Nonsense Mutation 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 1259/4058 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFP | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV56926632; called by muse, mutect2, varscan2
- ALDH3B2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs769140694, COSV62427929; called by muse, mutect2, varscan2
- AOC1 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370771602; called by muse, mutect2, varscan2
- AP002512.3 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs762884199, COSV54406824; called by muse, mutect2, varscan2
- APCDD1L | c.1475T>A p.V492D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV64487638; called by muse, mutect2, varscan2
- ARHGEF9 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53642755; called by muse, mutect2, varscan2
- C2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs771081314, COSV54961484; called by muse, mutect2
- CABP2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53709520; called by muse, mutect2
- CABS1 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs139939232; called by muse, mutect2, varscan2
- CAPN1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs749341081, COSV54200911; called by muse, mutect2, varscan2
- CCDC60 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs758751561, COSV59543259; called by muse, mutect2, varscan2
- CDK13 | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51705241; called by muse, mutect2, varscan2
- CKMT1B | c.1001T>G p.L334R | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV55853351; called by muse, mutect2, varscan2
- COL4A2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64632641; called by muse, mutect2, varscan2
- COL6A3 | c.4513C>T p.R1505C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs778816180, COSV55095416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP3A4 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547453529, COSV60501484; called by muse, mutect2, varscan2
- ELAVL2 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748871054, COSV56368747; called by muse, mutect2, varscan2
- EML2 | c.841+1G>A p.X281_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV55602982; called by muse, mutect2, varscan2
- ENAM | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 151/416 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1455436752, COSV68536777; called by muse, mutect2, varscan2
- F8 | c.1718G>T p.C573F | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM062688, CM153437, COSV64277474; called by muse, mutect2, varscan2
- FAM47A | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.093); catalogued as rs1279201108, COSV100649672, COSV60499173; called by muse, mutect2, varscan2
- GALNT13 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs759538738, COSV67234098; called by muse, mutect2, varscan2
- GBP5 | c.526T>A p.L176I | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV58594063; called by muse, mutect2
- IRF2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs754089440, COSV66930277; called by muse, mutect2, varscan2
- ITIH1 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs752754302, COSV56257759; called by muse, mutect2, varscan2
- KCNH1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751141740, COSV55076044; called by muse, mutect2, varscan2
- LARGE1 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as COSV61669372; called by muse, mutect2, varscan2
- MAGEB1 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV66776384; called by muse, mutect2, varscan2
- MAN2B2 | c.695G>A p.W232* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as COSV53455934; called by muse, mutect2, varscan2
- MVD | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs746569295, COSV56331542, COSV99964715; called by muse, mutect2, varscan2
- MXRA5 | c.5053A>G p.S1685G | Missense Mutation (SNP) | VAF 230/849 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54246076; called by muse, mutect2, varscan2
- NLRP11 | c.2658T>A p.H886Q | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV64088510; called by muse, mutect2, varscan2
- OCIAD1 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV51902019; called by muse, mutect2
- OR2T6 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs750710520, COSV63215692; called by muse, mutect2, varscan2
- OR5D13 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 130/399 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750305125, COSV62334227; called by muse, mutect2, varscan2
- PDE1A | c.585T>C p.I195= | Splice Region (SNP) | VAF 34/107 reads (32%) | catalogued as COSV59532952; called by muse, mutect2, varscan2
- PEX14 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63062958; called by muse, mutect2, varscan2
- PIP5K1C | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV58955116; called by muse, mutect2, varscan2
- POM121L12 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs775755313, COSV68694032; called by muse, mutect2, varscan2
- PRAMEF2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs267597976, COSV53578238; called by muse, mutect2, varscan2
- PSD4 | c.2387C>T p.T796M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55525049; called by muse, mutect2, varscan2
- RAD50 | c.1633A>G p.K545E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1253904315, COSV54756357; called by muse, mutect2, varscan2
- RBMS3 | c.1070T>G p.I357S (on ENST00000383767 / NM_001003793.3; = p.I339S on NM_001003792.3) | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV56162622; called by muse, mutect2, varscan2
- RGS21 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs369430749; called by muse, mutect2, varscan2
- STAG2 | c.2897C>A p.T966K | Missense Mutation (SNP) | VAF 86/352 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV54369282; called by muse, mutect2, varscan2
- STXBP5 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51656573; called by muse, mutect2, varscan2
- TDRD3 | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52161939; called by muse, mutect2, varscan2
- TENM1 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.529); catalogued as COSV64440167; called by muse, mutect2, varscan2
- THOC2 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55547841; called by muse, mutect2, varscan2
- TMEM163 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs145243913, COSV56111833; called by muse, mutect2, varscan2
- TRHDE | c.2452A>G p.I818V | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV53860606; called by muse, mutect2, varscan2
- TTN | c.27909G>T p.R9303S (on ENST00000591111; = p.R8376S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | PolyPhen benign (0.194); catalogued as COSV60271667; called by muse, mutect2, varscan2
- ZNF208 | c.2673T>A p.C891* | Nonsense Mutation (SNP) | VAF 51/188 reads (27%) | catalogued as COSV68111268; called by muse, mutect2, varscan2
- CACNG3 | c.267C>T p.Y89= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs368528326, COSV50086161; called by muse, mutect2, varscan2
- CLEC4D | c.480G>A p.T160= | Silent (SNP) | VAF 46/175 reads (26%) | catalogued as rs771336716, COSV55229241; called by muse, mutect2, varscan2
- DCSTAMP | c.579C>T p.V193= | Silent (SNP) | VAF 92/271 reads (34%) | catalogued as COSV52579499; called by muse, mutect2, varscan2
- FLNA | c.5967G>A p.P1989= (on ENST00000369850 / NM_001110556.2; = p.P1981= on NM_001456.3) | Silent (SNP) | VAF 66/221 reads (30%) | catalogued as rs372351673, COSV61043535; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2AC1 | c.210G>A p.A70= | Silent (SNP) | VAF 52/131 reads (40%) | catalogued as rs187505332, COSV51238038; called by muse, mutect2, varscan2
- IGHV3-35 | c.204G>A p.S68= | Silent (SNP) | VAF 102/298 reads (34%) | catalogued as rs751443166; called by muse, mutect2, varscan2
- MADCAM1 | c.357C>A p.T119= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV53130511; called by muse, mutect2, varscan2
- MAPK15 | c.708G>A p.P236= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs782526771, COSV62029665; called by muse, mutect2, varscan2
- OBSCN | c.10452G>A p.G3484= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV52814277; called by muse, mutect2, varscan2
- PCGF5 | c.765C>T p.F255= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs191746944, COSV60237229, COSV60237494; called by muse, mutect2, varscan2
- PPP2R5D | c.1047A>G p.Q349= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs973815515, COSV55151372; called by muse, mutect2, varscan2
- RNASE10 | c.486G>A p.K162= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs777764075, COSV60518199; called by muse, mutect2, varscan2
- RPGRIP1L | c.3153G>A p.Q1051= | Silent (SNP) | VAF 85/235 reads (36%) | catalogued as COSV50914089, COSV50919231; called by muse, mutect2, varscan2
- TCHHL1 | c.1455C>T p.N485= | Silent (SNP) | VAF 169/479 reads (35%) | catalogued as rs150195731, COSV64285426; called by muse, mutect2, varscan2
- TMEM215 | c.309C>T p.S103= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs535200766, COSV61363988; called by muse, mutect2, varscan2
- BIRC8 | n.1687_1688insC | RNA (INS) | VAF 86/388 reads (22%) | called by mutect2, pindel, varscan2
- C7orf66 | n.76C>A | RNA (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- CCNQP1 | n.426C>G | RNA (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
